Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8XI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8XI-01A (Primary Tumor).

[page 1 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

Surgical Pathology Report

Final

ICD-O-3

Carcinoma, squamous cell
NOS 8070/3

Site Cervix NOS C53.9

9/21/17/14

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

(Age: [REDACTED])

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED] M.D.

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
- LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old woman with a history of postmenopausal bleeding and a cervical lesion on examination.
Operative procedure: Cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description:

The specimen is received in a formalin-filled container labeled [REDACTED] and consists of multiple fragments of tan soft tissue measuring 1.5 x 1 x 0.2 cm in aggregate. Labeled A1. Jar 0.

[page 2 of 2]
Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available [REDACTED]

END OF REPORT

Page 2 of 2

Page: 2 of 2

Printed from [REDACTED]

Source: NCI Genomic Data Commons file 79d67026-b390-46c5-9dc7-8afde1a62eeb (TCGA-C5-A8XI.57D0E001-5535-4687-B04D-5CBEF5D6EF6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).